Somatic mutation profile of tumor specimen BA2489D (aliquot aq-BA2489D) from BEATAML1.0 case 2480, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.7 years (23,263 days).
Specimen BA2489D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 018476ce-e359-4f0a-bc0b-36ea40f598f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2030D (Solid Tissue Normal), aliquot aq-BA2030D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/421ae69a-e059-4fe1-b81f-ac117ddbb50f

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 7, RNA 1, Intron 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1934dup p.G646Wfs*12 | Frame Shift Ins (INS) | VAF 14/48 reads (29%) | hotspot (GDC flag); catalogued as rs750318549, COSV60102510; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- A2M | c.657C>A p.F219L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59386709; called by muse, mutect2, varscan2
- ATG14 | c.1231G>A p.G411R | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs865972356; called by muse, mutect2, varscan2
- OR4B1 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.578); catalogued as rs766076392; called by muse, mutect2
- OR6B2 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs532037194; called by muse, varscan2
- STAG2 | c.1840C>T p.R614* | Nonsense Mutation (SNP) | VAF 65/77 reads (84%) | catalogued as CM157403, COSV54351398; called by muse, mutect2, varscan2
- A2M | c.656T>A p.F219Y | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C8orf58 | c.483C>A p.D161E | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CACNA1G | c.2146C>A p.L716M | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, mutect2
- OR6B3 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- SLC5A7 | c.462C>A p.S154R | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.888); called by muse, mutect2
- TSHR | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 120/302 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- VPS13B | c.2428G>T p.A810S | Missense Mutation (SNP) | VAF 104/220 reads (47%) | SIFT tolerated (0.79); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- INSR | c.1083C>T p.T361= | Silent (SNP) | VAF 117/280 reads (42%) | catalogued as rs772597636; called by muse, mutect2, varscan2
- MS4A8 | c.576C>T p.C192= | Silent (SNP) | VAF 46/112 reads (41%) | called by muse, varscan2
- NYNRIN | c.3996A>G p.L1332= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as rs767235084, COSV66844656; called by muse, mutect2, varscan2
- PEX14 | c.945C>T p.G315= | Silent (SNP) | VAF 82/210 reads (39%) | catalogued as rs560264914; called by muse, mutect2, varscan2
- SH2D7 | c.534C>T p.P178= | Silent (SNP) | VAF 118/262 reads (45%) | catalogued as rs1272515752, COSV60928108; called by muse, mutect2, varscan2
- TAAR8 | c.204T>C p.F68= | Silent (SNP) | VAF 40/99 reads (40%) | called by muse, mutect2, varscan2
- TARS2 | c.7C>T p.L3= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as COSV64694763; called by muse, mutect2, varscan2
- AC103993.1 | n.126C>T | RNA (SNP) | VAF 55/153 reads (36%) | called by muse, varscan2
- ST8SIA5 | c.132-16792G>T | Intron (SNP) | VAF 51/102 reads (50%) | catalogued as rs1285782115; called by muse, varscan2
